Surgical pathology report (de-identified scan), TCGA case TCGA-CV-6953, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-6953-01A (Primary Tumor).

DIAGNOSIS

- (A) LEFT SUPRAOMOHYOID NECK DISSECTION:
Twenty-seven lymph nodes, no tumor present (0/7 submental-submaxillary, 0/5 subdigastric; 0/1 midjugular; 0/10 upper posterior cervical; 0/4 mid posterior cervical).
Submental gland, no pathologic abnormality.
- (B) RIGHT SUPRAOMOHYOID NECK DISSECTION:
Six lymph nodes, no tumor present (0/5 submental-submaxillary, 0/1 subdigastric).
Submental gland, no pathologic abnormality.
- (C) MENTAL NERVE:
Segment of nerve and fibrovascular tissue, no tumor present.
- (D) FLOOR OF MOUTH AND ANTERIOR MANDIBLE:
WELL DIFFERENTIATED INVASIVE SQUAMOUS CELL CARCINOMA
(4.5 X 3.5 X 2.0 CM) WITH VERRUCOUS FEATURES.
VASCULAR INVASION PRESENT.
Mucosal and soft tissue margins of resection, free of tumor.
Ulcer, granulation tissue and marked acute and chronic inflammation consistent with previous biopsy site.
Portion of mandible (gross only).
- (E) LEFT POSTERIOR RIDGE
Focal parakeratosis, acanthosis and marked chronic inflammation, no tumor present.
- (F) TEETH:
Teeth, gross only.

SPECIMEN

- (A) LEFT SUPRAOMOHYOID NECK DISSECTION:
(B) RIGHT SUPRAOMOHYOID NECK DISSECTION:
(C) MENTAL NERVE:
(D) FLOOR OF MOUTH AND ANTERIOR MANDIBLE:
(E) LEFT POSTERIOR RIDGE
(F) TEETH:

Source: NCI Genomic Data Commons file 09ae58d5-5f1a-4630-98a0-8dd9c53ccc7b (TCGA-CV-6953.446618C2-6DF4-47CD-B808-81BC9CF0C6F6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).